Gene-level copy-number profile of tumor specimen TCGA-A7-A3IZ-01A from TCGA case TCGA-A7-A3IZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.0 years (22,997 days).
Specimen TCGA-A7-A3IZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a5acf8e3-4062-4ee9-a31f-5ab07d991230.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A3IZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8b9cbdf5-9b45-484a-838f-35a66d9b7a9b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,220; copy number 3: 1,448; copy number 4: 47,810; copy number 5: 98; copy number 6: 2,604; copy number 7: 9; copy number 10: 53; copy number 11: 138; copy number 14: 41; copy number 16: 127; copy number 17: 13; copy number 19: 131; copy number 25: 39; copy number 27: 12; copy number 30: 37; copy number 40: 7; copy number 41: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A3IZ-01A-11D-A20R-01): tumor purity 0.9, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 626 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:35,235,475–35,796,550, 1 gene, copy number 14 (within-gene range 7–14): UNC5D.
- chr8:35,525,176–42,101,836, 136 genes, copy number 11–41 (broad region; genes not listed).
- chr8:42,697,366–43,085,788, 13 genes, copy number 17 (within-gene range 4–17): CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA.
- chr11:65,745,729–78,079,865, 476 genes, copy number 10–30 (within-gene range 2–30) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
